Somatic mutation profile of tumor specimen HCM-BROD-0709-C64-01A (aliquot HCM-BROD-0709-C64-01A-01D-A85K-36) from HCMI case HCM-BROD-0709-C64, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 47.1 years (17,200 days).
Specimen HCM-BROD-0709-C64-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 339d84f7-e41f-4809-a3f1-73bbb31886c0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0709-C64-11B (Solid Tissue Normal), aliquot HCM-BROD-0709-C64-11B-01D-A85K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/619be5a3-be37-4b27-8453-009457dbc024

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 2, Frame Shift Ins 1, Splice Site 1, Nonsense Mutation 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BBS4 | c.614T>G p.L205R | Missense Mutation (SNP) | VAF 88/210 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755843033; called by muse, mutect2, varscan2
- IGSF9 | c.3460C>T p.R1154C (on ENST00000368094 / NM_001135050.2; = p.R1138C on NM_020789.4) | Missense Mutation (SNP) | VAF 164/578 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs767665145; called by muse, varscan2
- NECAB2 | c.758G>T p.S253I | Missense Mutation (SNP) | VAF 21/302 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs780465946; called by muse, mutect2
- B3GALNT2 | c.538dup p.Y180Lfs*41 | Frame Shift Ins (INS) | VAF 92/376 reads (24%) | called by mutect2, pindel, varscan2
- CNOT2 | c.49-1G>A p.X17_splice | Splice Site (SNP) | VAF 12/194 reads (6%) | called by muse, mutect2
- DUOX2 | c.2305G>T p.E769* | Nonsense Mutation (SNP) | VAF 114/288 reads (40%) | called by muse, mutect2, varscan2
- ECE1 | c.724A>G p.S242G | Missense Mutation (SNP) | VAF 137/169 reads (81%) | SIFT tolerated (0.68); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OGT | c.651T>C p.A217= | Splice Region (SNP) | VAF 106/266 reads (40%) | called by muse, mutect2, varscan2
- ANKRD62 | c.720A>G p.A240= | Silent (SNP) | VAF 123/322 reads (38%) | catalogued as rs551309335; called by muse, mutect2, varscan2
- RTL8A | c.216C>T p.L72= | Silent (SNP) | VAF 286/610 reads (47%) | catalogued as COSV66188366; called by muse, mutect2, varscan2
- KCTD1 | c.-15-46439C>T | Intron (SNP) | VAF 182/412 reads (44%) | catalogued as rs1389078626; called by muse, mutect2, varscan2
